Somatic mutation profile of tumor specimen ALCH-B36D-TTP1-A (aliquot ALCH-B36D-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B36D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.2 years (18,718 days).
Specimen ALCH-B36D-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 665832ce-3032-48b4-91c4-59b15b340fe9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B36D-NB1-A (Blood Derived Normal), aliquot ALCH-B36D-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d483bb7e-56e4-49c9-ac74-25261b148d74

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1, In Frame Ins 1, Intron 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD40LG | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs768138040, COSV65699185; called by muse, mutect2, varscan2
- ITGB7 | c.149C>G p.S50C | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57240255; called by muse, mutect2, varscan2
- LILRB1 | c.1213C>A p.L405I (on ENST00000427581; = p.L369I on NM_006669.6) | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV61115814; called by muse, mutect2, varscan2
- PARP1 | c.1519dup p.S507Kfs*14 | Frame Shift Ins (INS) | VAF 30/170 reads (18%) | catalogued as rs1159330096; called by mutect2, varscan2
- SPEG | c.2776C>T p.R926W | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs763189226, COSV56667348; called by muse, mutect2
- AKAP9 | c.5130_5132dup p.E1710dup | In Frame Ins (INS) | VAF 20/158 reads (13%) | called by pindel, varscan2
- COL8A1 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT18 | c.347_348del p.Q116Lfs*22 | Frame Shift Del (DEL) | VAF 22/162 reads (14%) | called by mutect2, pindel, varscan2
- IDO1 | c.101A>G p.D34G | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- IFT122 | c.2887-2A>G p.X963_splice (on ENST00000348417 / NM_052989.3; = p.X904_splice on NM_018262.4) | Splice Site (SNP) | VAF 54/354 reads (15%) | called by muse, mutect2, varscan2
- PCDHB4 | c.1861G>A p.G621S | Missense Mutation (SNP) | VAF 104/642 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SELENOP | c.4T>C p.W2R | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TAF4 | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 31/196 reads (16%) | called by muse, mutect2, varscan2
- TEAD2 | c.1323_1324del p.Y442Pfs*39 | Frame Shift Del (DEL) | VAF 54/246 reads (22%) | called by mutect2, pindel, varscan2
- TNPO2 | c.311T>A p.I104N | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, varscan2
- WDR87 | c.4342C>A p.L1448M | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- FAM184A | c.1713A>T p.G571= | Silent (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- GRM3 | c.1773A>G p.T591= | Silent (SNP) | VAF 52/290 reads (18%) | catalogued as rs769178586; called by muse, mutect2, varscan2
- IL23R | c.120A>G p.T40= | Silent (SNP) | VAF 60/231 reads (26%) | called by muse, mutect2, varscan2
- KIF14 | c.1251C>T p.Y417= | Silent (SNP) | VAF 40/237 reads (17%) | catalogued as rs199789511; called by muse, mutect2, varscan2
- MYRF | c.915G>A p.P305= (on ENST00000278836 / NM_001127392.3; = p.P296= on NM_013279.4) | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs778037643, COSV53892387; called by mutect2, varscan2
- ZNF764 | c.1044C>T p.C348= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs770617243, COSV53221283; called by mutect2, varscan2
- AL008638.2 | n.327G>A | RNA (SNP) | VAF 52/294 reads (18%) | catalogued as rs1156591555; called by muse, mutect2, varscan2
- NME1 | c.228+37T>A | Intron (SNP) | VAF 87/384 reads (23%) | catalogued as rs373681502; called by muse, mutect2, varscan2
